Gene-level copy-number profile of tumor specimen TCGA-CF-A47V-01A from TCGA case TCGA-CF-A47V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 52.7 years (19,265 days).
Specimen TCGA-CF-A47V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fa635ffb-77df-445b-b80d-8b0050069ac6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CF-A47V-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2807ae2a-d3d4-446e-b1d5-bafc5f946503

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,876; copy number 2: 50,215; copy number 3: 5,650; copy number 10: 21; copy number 11: 29; copy number 16: 10; copy number 17: 7; copy number 19: 6; copy number 25: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CF-A47V-01A-11D-A23T-01): tumor purity 0.93, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,100,016–1,288,291, 10 genes, copy number 16: AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT.
- chr4:1,712,821–2,841,098, 31 genes, copy number 10–25 (within-gene range 2–25): AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2, COX6B1P5, MXD4, MIR4800, ZFYVE28, AL158068.2, RN7SL589P, AL158068.1, CFAP99, RNF4, AL645924.1, AL645924.2, FAM193A, CR545473.1, Y_RNA, TNIP2, SH3BP2.
- chr11:69,072,915–69,162,440, 1 gene, copy number 11 (within-gene range 2–11): AP003071.5.
- chr11:69,103,493–70,207,390, 30 genes, copy number 11–19: AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1.
- chr11:70,278,921–70,363,368, 4 genes, copy number 11 (within-gene range 2–11): H2AZP4, AP002336.2, MIR548K, AP002336.1.

Autosomal genes at a single copy (total copy number 1): 1,495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
